Somatic mutation profile of tumor specimen TCGA-13-1492-01A (aliquot TCGA-13-1492-01A-01W-0545-08) from TCGA case TCGA-13-1492, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.6 years (24,332 days).
Specimen TCGA-13-1492-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4809c7cb-6186-46d9-a94a-213bf09a30c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1492-10A (Blood Derived Normal), aliquot TCGA-13-1492-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c5aaab3-b4ef-4e46-8bcd-bd6803c21ffb

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Del 3, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MLH1 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 104/237 reads (44%) | catalogued as rs63751221, CM990855, COSV51614696; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1458del p.L486Ffs*9 | Frame Shift Del (DEL) | VAF 25/35 reads (71%) | catalogued as rs1555286611; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 71/75 reads (95%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, mutect2, varscan2
- AKAP3 | c.764G>T p.R255I | Missense Mutation (SNP) | VAF 175/225 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.276); catalogued as COSV57416178, COSV57418116; called by muse, mutect2, varscan2
- CACNA1C | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.945); catalogued as rs794727961, COSV59753826; ClinVar: uncertain significance; called by muse, mutect2
- CUL7 | c.2833A>G p.I945V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs778862752, COSV54820282; called by muse, mutect2, varscan2
- CUX1 | c.1921C>G p.L641V | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs1398246789, COSV52909606; called by muse, mutect2, varscan2
- CYP2F1 | c.1318T>C p.S440P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1401428092, COSV58528460; called by muse, mutect2
- FGF23 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1384170096, COSV52975192; called by muse, mutect2, varscan2
- KIT | c.2867G>A p.R956Q | Missense Mutation (SNP) | VAF 101/113 reads (89%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs139694927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PINK1 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.22); catalogued as rs773843241, CM1212782, COSV58632262; called by mutect2, varscan2
- PTEN | c.697del p.R233Dfs*23 | Frame Shift Del (DEL) | VAF 232/338 reads (69%) | catalogued as CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; called by mutect2, pindel, varscan2
- TFR2 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs776047688, CM161229, COSV56155673; called by muse, mutect2, varscan2
- ZNF135 | c.677G>T p.S226I (on ENST00000313434 / NM_001289401.2; = p.S238I on NM_003436.4) | Missense Mutation (SNP) | VAF 107/180 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as COSV100536352, COSV57882921; called by muse, mutect2, varscan2
- DAD1 | c.20_21del p.S7Cfs*89 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | called by mutect2, pindel, varscan2
- KCNF1 | c.753G>A p.A251= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs1037277372, COSV54464817; called by muse, mutect2, varscan2
- TEP1 | c.7875T>C p.N2625= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs760883519, COSV52997098; called by muse, mutect2, varscan2
- TNN | c.1707C>T p.D569= | Silent (SNP) | VAF 51/93 reads (55%) | catalogued as rs140149976; called by muse, mutect2, varscan2
- ZFYVE26 | c.2451G>A p.L817= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV61331807; called by muse, mutect2, varscan2
- TTN | c.34265-5221G>T | Intron (SNP) | VAF 135/279 reads (48%) | catalogued as COSV100588179; called by muse, mutect2, varscan2
